Surgical pathology report (de-identified scan), TCGA case TCGA-XE-AAOO, project TCGA-TGCT (Testicular Germ Cell Tumors), specimen TCGA-XE-AAOO-01A (Primary Tumor).

[page 1 of 2]
ICD O-3
Seminoma NOS 9061/3
Site (P) Testis NOS C62.9
9/53/21/14

Name:

Operative procedure: RADICAL ORCHIECTOMY

- Specimen Source: TESTIS
- Gross Exam Date:
- Physician:

Pager No.:

DIAGNOSIS (based on GROSS and MICROSCOPIC examination):

TESTIS: RADICAL ORCHIECTOMY

Specimen Laterality: Right

Tumor Focality: Unifocal

Tumor Size: 15.5 x 9.5 x 8 cm

Macroscopic Extent of Tumor: Confined to testis. Tumor extends to hilar fat

Histologic Type: Seminoma

Margins: Spermatic cord margin free of tumor

Microscopic Tumor Extension: Does not extend to spermatic cord.

Lymph-Vascular Invasion: Lymphovascular invasion not definitely identified.

Pathologic Staging: (pTNX)

Primary Tumor (pT1): N/A

Regional Lymph Nodes (pN): N/A

Specify: Number examined: 0

Number involved: 0

Distant Metastasis (pM): N/A

Comments: No testicular parenchymal tissue identified. The seminoma is c-Kit positive and CD30 negative. The finding confirms the diagnosis.

IN PT. ☐ COST CODE	CLINIC/WARD/NURSING STATION	PATIENT IDENTIFICATION
---	-----------------------------	------------------------

SURGICAL PATHOLOGY TISSUE REPORT

[page 2 of 2]
Name: _____ Sex: _____

Operative Procedure: RADICAL ORCHIECTOMY

- Specimen Source: TESTIS
- Gross Exam Date:
- Physician:

Pager No.:

Immunohistochemistry Disclaimer

This test was developed and its performance characteristics determined by

It has not been cleared or approved by the U.S. Food and Drug Administration. The FDA has determined that such clearance or approval is not necessary. This test is used for clinical purposes. It should not be regarded as investigational or for research. This laboratory is certified under the Clinical Laboratory Improvement Amendment of 1988 (CLIA) as qualified to perform high complexity clinical laboratory testing.

GROSS DESCRIPTION:

The specimen is received in one part labeled with patient's name, hospital number and right testis. It consists of a 390 gram orchiectomy specimen including 15 x 9.5 x 8 cm testis and 2.5 x 1 x 0.5 cm epididymis and 4.5 cm in length and 1.3 cm in diameter spermatic cord. After sectioning there is 14 x 9 x 8 cm white-tan, fleshy, variegated, well circumscribed mass with focal areas of necrosis. There is no gross involvement of tunica albuginea or epididymis. The mass has replaced all of the testis. No testicular parenchyma identified. The spermatic cord consists of vas deferens, arteries and veins and is unremarkable. R12.

Cassette 1-5, tumor.

Cassettes 6 and 7, tumor and base of epididymis.

Cassette 8, spermatic cord resection margin.

Cassette 9, spermatic cord mid portion.

Cassette 10, spermatic cord, peritesticular portion.

Cassettes 11-12, tumor and tunica vaginalis.

IN PT. ☐ COST CODE	CLINIC/WARD/NURSING STATION	PATIENT IDENTIFICATION
---	-----------------------------	------------------------

SURGICAL PATHOLOGY TISSUE REPORT

PAGE 2

Source: NCI Genomic Data Commons file 806326c2-d809-4193-8c45-459406e74592 (TCGA-XE-AAOO-01A.pdf), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).